Surgical pathology report (de-identified scan), TCGA case TCGA-55-8207, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8207-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

* Final Report *

Clinical History

Left lower lobe lung cancer

Specimen

- #1 Level 4 left lymph node
- #2 Level 2 left lymph node
- #3 Level 7 lymph node
- #4 Level 4 right lymph node
- #5 Level 11 lymph node
- #6 Bronchial margin main bronchus and superior segment bronchus
- #7 Additional Level 11 lymph node
- #8 Level 10 lymph node

Gross Examination

#1 The first specimen received fresh, level 4 left lymph node, is a 1.1 x 0.5 x 0.5 cm blue-gray and tan-pink aggregate of soft tissue. All of the tissue is submitted for frozen section in one block.

#2 The second specimen received fresh, labeled level 2 left lymph node, is a 1.2 x 1.0 x 0.6 cm aggregate of dark blue-gray and tan-pink soft tissue. All of the tissue is submitted for frozen section in one block.

#3 The third specimen received fresh labeled level 7 lymph node, is a 0.6 x 0.5 x 0.2 cm aggregate of two pieces of blue-gray, soft tissue. All of the tissue is submitted for frozen section in one block.

#4 The fourth specimen received fresh, level 4 right lymph node, is a 1.5 x 1.0 x 0.5 cm aggregate of blue-gray tissue fragments. All of the tissue is submitted for frozen section in two blocks.

#5 Labeled level 11 lymph node is a 2.4 x 2.0 x 1.0 cm aggregate of three

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

fragments of red-black lymphoid tissue. It is entirely submitted as five sections in three: "A"- "C". Block Summary: "A", two smaller fragments, entirely submitted; "B", "C", largest fragment, trisected. [REDACTED]

#6 Received fresh for Frozen Section, placed in formalin and labeled bronchial margin, main bronchus and superior segment bronchus, is a 326.8 gram, 15.0 x 11.5 x 4.5 cm lobe of lung. The bronchial margin is submitted for Frozen Section as "3FS". Adjacent to the bronchus is a 6.5 cm long staple line. Approximately 5.0 cm from the bronchus on the opposite surface of the lobe, the pleura is focally retracted over an area of 2.5 cm (inked black). Sectioning through this area demonstrates a 4.0 x 3.8 x 2.2 cm ill-defined pale tan grey mass, coming to within 0.1 cm of the overlying pleura, and 3.5 cm from the bronchial margin. The parenchyma otherwise is dark red to tan red, soft and spongy. There are no additional lesions identified. There are no lobar lymph node candidates identified. Seven representative sections are submitted in five: "A-E". Block summary: "A", vascular margin, tangential; "B-D", mass with overlying pleura (inked black), perpendicular; "E", uninvolved parenchyma.

#7 Labeled additional Level 11 lymph node, is a 2.3 x 1.3 x 0.8 cm portion of dark grey red soft tissue, bisected and entirely submitted in one cassette.

#8 Labeled Level 10 lymph node, is a 1.1 x 1.0 x 0.5 cm ovoid fragment of dark grey red soft tissue, bisected and entirely submitted in one cassette. [REDACTED]

Frozen Section Diagnosis

- #1 LYMPH NODE, 4L, BIOPSY: (1 FS): NEGATIVE FOR CARCINOMA. [REDACTED]
- #2 LYMPH NODE, LEVEL 2 LEFT (1 FS): NEGATIVE FOR CARCINOMA. [REDACTED]
- #3 LYMPH NODE LEVEL 7 (1 FS): NEGATIVE FOR CARCINOMA. [REDACTED]
- #4 LYMPH NODE, LEVEL 4 RIGHT (2 FS): NEGATIVE FOR CARCINOMA. [REDACTED]
- #6 BRONCHIAL MARGIN, MAIN BRONCHUS AND SEGMENT OF BRONCHUS (1FS): BRONCHIAL MARGIN, NEGATIVE. REPORTED TO DR. [REDACTED]

Microscopic Examination

#1-8 Microscopic examination performed. An elastic tissue stain was performed on two blocks from specimen #6 to assist with pleural status assessment. [REDACTED]

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

Final Diagnosis

- #1 LYMPH NODE, LEFT LEVEL 4, BIOPSY: NEGATIVE FOR CARCINOMA.
- #2 LYMPH NODE, LEFT LEVEL 2, BIOPSY: NEGATIVE FOR CARCINOMA.
- #3 LYMPH NODE, LEVEL 7, BIOPSY: NEGATIVE FOR CARCINOMA.
- #4 LYMPH NODE, RIGHT LEVEL 4, BIOPSY: NEGATIVE FOR CARCINOMA.
- #5 LYMPH NODE, LEVEL 11, BIOPSY: NEGATIVE FOR CARCINOMA.
- #6 LUNG, LEFT LOWER LOBE, RESECTION: INVASIVE ADENOCARCINOMA, ACINAR
PREDOMINANT.

HISTOLOGIC GRADE: WELL DIFFERENTIATED.

TUMOR SIZE: 4.0 X 3.8 X 2.2 CM.

PROXIMAL BRONCHIAL RESECTION MARGIN STATUS: NEGATIVE FOR CARCINOMA.

PLEURAL SURFACE STATUS: NEGATIVE FOR VISCERAL PLEURA INVASION.

DIRECT EXTENSION OF TUMOR: NONE IDENTIFIED.

LYMPHOVASCULAR SPACE STATUS: NEGATIVE.

ADDITIONAL PATHOLOGIC FINDINGS: NONE IDENTIFIED.

LYMPH NODE STATUS: NO ATTACHED LYMPH NODES.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2a pN0.

- #7 LYMPH NODE, ADDITIONAL LEVEL 11, BIOPSY: NEGATIVE FOR CARCINOMA.

- #8 LYMPH NODE, LEVEL 10, BIOPSY: NEGATIVE FOR CARCINOMA.

Signature Line

Signed by:

ELECTRONIC SIGNATURE

Ordering Provider

Ordering Physician:

Printed by:

Printed on:

Source: NCI Genomic Data Commons file 281a971b-b794-45e2-9193-ec8fc6d72df6 (TCGA-55-8207.BF8AF6E0-1EA5-4281-A00D-42AA138D781F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).